CGCI case BLGSP-71-30-00652 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/abcc330d-0399-4d18-9b02-6fc6d614711e

Demographics
Sex at birth: female; Age at index: 60 years; Vital status: Alive.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Specified parts of peritoneum; Classification of tumor: primary; Age at diagnosis: 60.9 years (22,233 days); Year of diagnosis: 2010; Method of diagnosis: Excisional Biopsy; Ann Arbor pathologic stage: Stage IV; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,638 days (4.5 years); Ann Arbor extranodal involvement: Yes; Burkitt lymphoma clinical variant: Sporadic, adult; Max tumor bulk site: Ovary; Sites of involvement: Ovary, NOS / Soft tissue / Omentum.
   Pathology details: Bone marrow malignant cells: No; Tumor largest dimension diameter: 5.7 cm.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Regimen or line of therapy: R-IVAC; Days to treatment start: 7 days; Days to treatment end: 32 days; Number of cycles: 4; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Regimen or line of therapy: R-CODOX-M; Days to treatment start: 7 days; Days to treatment end: 32 days; Number of cycles: 4; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Regimen or line of therapy: R-CHOP; Days to treatment start: 7 days; Days to treatment end: 32 days; Number of cycles: 4; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Cytarabine + Doxorubicin + Etoposide + Ifosfamide + Methotrexate + Prednisone + Rituximab + Vincristine; Initial disease status: Initial Diagnosis; Days to treatment start: 7 days; Days to treatment end: 32 days; Number of cycles: 4; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Initial disease status: Initial Diagnosis; Days to treatment start: 113 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 0 days; ECOG performance status: 1.
- Days to follow up: 1,638 days (4.5 years); Disease response: Tumor Free.

Molecular and laboratory tests
- BCL2 (FISH): Normal.
- BCL2 (IHC): Negative.
- BCL6 (FISH): Normal.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MIB1 (IHC): Positive.
- MYC translocation (FISH): Abnormal, NOS.
- Lactate Dehydrogenase 1158 [Blood test normal range upper: 618].

Other clinical attributes
- Day 0: Weight: 61.4 kg; Height: 173 cm; BMI: 20.5.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-30-00652-01A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Other; Preservation method: FFPE; Days to sample procurement: 0 days; Method of sample procurement: Excisional Biopsy; Tissue collection type: Retrospective.
- Sample BLGSP-71-30-00652-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Biospecimen anatomic site: Lymph Node.
- Sample BLGSP-71-30-00652-01Z: Sample type: Tumor; Tissue type: Tumor.
  Slide BLGSP-71-30-00652-01-CD10: Tissue microarray coordinates: K4,L4.
  Slide BLGSP-71-30-00652-01-CD20: Tissue microarray coordinates: K4,L4.
  Slide BLGSP-71-30-00652-01-BCL6: Tissue microarray coordinates: K4,L4.
  Slide BLGSP-71-30-00652-01-CD3: Tissue microarray coordinates: K4,L4.
  Slide BLGSP-71-30-00652-01-BCL2: Tissue microarray coordinates: K4,L4.
  Slide BLGSP-71-30-00652-01-EBER: Tissue microarray coordinates: K4,L4.
  Slide BLGSP-71-30-00652-01-Ki67: Tissue microarray coordinates: K4,L4.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Lost to follow-up: Yes; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), classic morphology; Extranodal site involvement: 2; Extranodal involvment other: soft tissue to omentum thickening; Lymph nodes examined: No.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: No Known Nodal Involvement.
- Stage record, Ann arbor: B symptoms present indicator: Yes.
- Tests performed: LDH level: 1158; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 5: Immunophenotypic analysis tested: BCL2.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunophenotypic analysis tested: MIB-1.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 1: Genetic abnormality tested: C-myc.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 2: Genetic abnormality tested: BCL2.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 3: Genetic abnormality tested: BCL6.
- Treatments, Treatment 1: Therapy regimen: Initial; Chemo end reporting period: Yes; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharmaceutical regimen other: CHOPR (x1), CODOXMR/IVACR/CODOXMR (Magrath protocol 1A/1B, 2A); Pharma adjuvant cycles count: 4.
- Treatments, Treatment 2: Therapy regimen: Initial; Treatment type: Stem Cell Transplant; Stem cell transplantation: Autologous.

Additional fields from the CGCI biospecimen supplement workbook CGCI-BLGSP_biospecimenSupplementSpreadsheet_TWIST_20220304.xlsx (sheet Sheet1), for sample BLGSP-71-30-00652-01A-01E-0001-01:
- % tumour: 95
